Surgical pathology report (de-identified scan), TCGA case TCGA-FV-A23B, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FV-A23B-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Carcinoma, hepatocellular, nos 8170/3

Site: Liver C22.0 /w 4/19/11

Not for Permanent Storage in Medical Records / Not Valid for Signing

Ordering Provider
Result Provider
Report Name : Surgical Report

Case is (C) (C) (C)		☒

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE:

----- SPECIMEN DESCRIPTION: -----

- A. SEGMENT 8 LIVER BIOPSY, APC
B. RE-RESECTION OF GROSSLY POSITIVE LIVER MARGINS

----- PRE-OPERATIVE DIAGNOSIS: -----

None provided

----- POST-OPERATIVE DIAGNOSIS: -----

None provided

----- CLINICAL INFORMATION: -----

Biopsy-proven primary biliary cirrhosis with two separate foci of hepatitis C

----- INTRAOPERATIVE CONSULTATION: -----

APC DIAGNOSIS: "Specimen oriented; tumor submitted for genomics" by [REDACTED]

T:

----- GROSS DESCRIPTION: -----

(Parts A and B are received in the same container).
A/APC & B. The specimen consists of one portion of roughly ovoid, tan-brown hepatic tissue. The deep surface reveals a portion of loosely attached, irregular hepatic tissue. The larger portion is part A, and the smaller portion on the deep surface is part B. Part B is sutured to part A by two blue sutures. The entire specimen measures 9.3 x 8.0 x 3.5 cm and weighs 121 grams. The attached part B portion measures 3.0 x 2.5 x 1.2 cm. The capsular surface is smooth and tan-brown. The deep surfaces of part A and part B are inked black, and the specimen is serially sectioned. The sections show two well-defined, tan-brown nodules, measuring 2.2 x 2.0 x 1.8 cm and 4.5 x 3.4 x 3.0 cm. The smaller nodule is composed of lobulated, tan-white to tan-brown tissue with focal hemorrhage. The larger nodule is composed of tan-white, firm tissue with focal hemorrhage. The smaller nodule is 0.2 cm from the surgical resection surface, and the larger nodule is 0.4 cm from the surgical resection surface. The two nodules are 0.8 cm away from each other. Both nodules bulge over the capsular surface. The sections away from the nodule reveal lobulated, tan-brown, coarse hepatic parenchyma. The section away from the two nodules is not normal homogeneous liver tissue. However, no discrete fibrotic nodules can be identified. The part B portion is close to the deep surface of the larger nodule, and the sections show the same lobulated, tan-brown coarse parenchyma. Representative sections are submitted in fourteen cassettes as follows: cassette A1 - smaller nodule, with deep margin; cassettes A2 through A4 - smaller nodule; cassette A5 - larger nodule, with deep margin; cassettes A6 through A8 - sections of the larger nodule;

[page 2 of 2]
Not for Permanent Storage in Medical Records / Not Valid for Signing

[REDACTED]
[REDACTED]
[REDACTED]
Result Provider :
Report Name :Surgical Report

cassettes A9 and A10 - sections away from the two nodules from part A;
cassettes B1 through B4 - entire B portion.

T:

==== MICROSCOPIC DESCRIPTION: =====

A/APC & B. Sections of part A are examined on ten slides. A1 through A10. Sections of part B represents section examined on four slides B1 and B2. Multiple sections of the liver show a background of cirrhosis characterized by anastomosing bands of fibrous tissue with regenerating nodules. Tissue shows two separate nodules of hepatocellular carcinoma. There are areas with trabecular pattern, as well as glandular and small cell pattern. Also present are congested blood vessels. The tumors are subcapsular. The overall sections of the margin on slides B1 through B4 show no tumor.

==== FINAL DIAGNOSIS: =====

A/APC & B. LIVER, SEGMENT EIGHT, WEDGE EXCISIONAL AND ADDITIONAL MARGIN:

1. HEPATOCELLULAR CARCINOMA, WELL DIFFERENTIATED
2. CLEAR TRUE SURGICAL RESECTION MARGIN
3. BACKGROUND OF CIRRHOSIS

A-MALIGNANT

C

T.

[REDACTED]
(Electronic Signature)

DATE AND TIME OF REPORT:

Source: NCI Genomic Data Commons file 64efc5cb-9f13-4b41-a8b7-8fb8f62927a8 (TCGA-FV-A23B.82010944-23DA-4FC5-934B-05AB3C238467.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).